Gene-level copy-number profile of specimen HCM-SANG-0302-C15-85A from HCMI case HCM-SANG-0302-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0302-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 916a76b5-a9f9-4bb0-a1dc-769ec560d64a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0302-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/a996af21-62cf-444f-b238-607d74ed6e35

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 35; copy number 2: 13,875; copy number 3: 33,075; copy number 4: 6,816; copy number 5: 1,795; copy number 6: 2,298; copy number 7: 645; copy number 8: 29; copy number 9: 11; copy number 10: 40; copy number 11: 9; copy number 12: 68; copy number 13: 59; copy number 16: 21; copy number 17: 44; copy number 18: 47; copy number 19: 21; copy number 21: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 997 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,302,466–47,832,780, 168 genes, copy number 8–17 (broad region; genes not listed).
- chr7:55,019,017–55,595,006, 11 genes, copy number 10–18: EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.
- chr8:92,402,920–112,148,825, 330 genes, copy number 7 (broad region; genes not listed).
- chr8:116,845,934–128,564,679, 179 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:129,241,228–129,291,275, 3 genes, copy number 7: AC103833.2, AC103833.1, RN7SKP206.
- chr8:139,108,430–143,299,952, 87 genes, copy number 7 (broad region; genes not listed).
- chr8:143,368,876–143,384,221, 1 gene, copy number 7: RHPN1.
- chr9:35,147,410–38,068,687, 96 genes, copy number 8–21 (within-gene range 3–21) (broad region; genes not listed).
- chr9:37,915,898–38,069,227, 1 gene, copy number 19 (within-gene range 3–19): SHB.
- chr11:41,714,534–42,253,721, 6 genes, copy number 9–10: LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr14:18,333,726–18,712,643, 22 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:22,197,446–22,482,959, 1 gene, copy number 7 (within-gene range 5–7): AC244502.1.
- chr14:22,265,749–22,423,042, 9 genes, copy number 7 (within-gene range 5–7): TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2.
- chr14:22,462,932–22,482,346, 10 genes, copy number 7 (within-gene range 5–7): TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr14:80,197,526–80,455,469, 2 genes, copy number 7: DIO2, DIO2-AS1.
- chr14:106,821,174–106,879,812, 10 genes, copy number 8: IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:39,238,466–40,527,002, 59 genes, copy number 16–18: AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr18:39,034,007–39,034,110, 1 gene, copy number 10: RNU6-706P.

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
